Somatic mutation profile of tumor specimen TCGA-DJ-A13S-01A (aliquot TCGA-DJ-A13S-01A-11D-A10S-08) from TCGA case TCGA-DJ-A13S, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 19.4 years (7,099 days).
Specimen TCGA-DJ-A13S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd365d7d-9121-407b-a564-6e3a884a6f01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A13S-10A (Blood Derived Normal), aliquot TCGA-DJ-A13S-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/930d8887-17cd-4b8a-9c55-6a9e8d1faabd

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 135/347 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BOC | c.1311C>A p.N437K | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV56355261; called by muse, mutect2
- CDKL5 | c.2768G>A p.R923H | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs1487927674, COSV101183851, COSV66107237; called by muse, mutect2, varscan2
- EPB41L1 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52436790; called by muse, mutect2, varscan2
- NAV3 | c.1688A>C p.Q563P | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV57100275; called by muse, mutect2, varscan2
- RAB3C | c.421G>T p.V141F | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51439701; called by muse, mutect2, varscan2
- TG | c.2766_2791del p.G923Cfs*6 | Frame Shift Del (DEL) | VAF 34/166 reads (20%) | called by mutect2, pindel
- MATR3 | c.69G>A p.A23= | Silent (SNP) | VAF 69/246 reads (28%) | catalogued as rs750693851, COSV63075457; called by muse, mutect2, varscan2
- XIRP2 | c.6786G>A p.K2262= (on ENST00000628543; = p.K2437= on NM_152381.6) | Silent (SNP) | VAF 53/154 reads (34%) | catalogued as COSV54721011; called by muse, mutect2, varscan2
